Somatic mutation profile of tumor specimen HTMCP-03-06-02370-01A (aliquot HTMCP-03-06-02370-01A-01D-10409) from CGCI case HTMCP-03-06-02370, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2.
Specimen HTMCP-03-06-02370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbfe83b3-fb87-4539-b442-49cddce79a6d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02370-10A (Blood Derived Normal), aliquot HTMCP-03-06-02370-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/993ff58b-c901-4de5-a92a-75bf472b4245

The open-access MAF lists 59 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 6, Splice Site 1, Frame Shift Del 1, RNA 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 37/118 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101229454, COSV67961584, COSV67961602; called by muse, varscan2
- AQP2 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs369214822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH6 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV99420851; called by muse, mutect2
- CFAP47 | c.1432C>G p.P478A | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52882486, COSV52890211; called by muse, mutect2, varscan2
- CHIA | c.1069G>A p.A357T (on ENST00000343320; = p.A249T on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201691527; called by muse, mutect2, varscan2
- CKAP5 | c.4535A>G p.D1512G | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs912595270; called by muse, mutect2, varscan2
- COL1A2 | c.2987G>A p.R996K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV51958652; called by muse, mutect2, varscan2
- CTNNA2 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV63544474; called by muse, mutect2
- DCLK3 | c.800T>A p.M267K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760049057; called by muse, mutect2, varscan2
- DNAH9 | c.11599C>T p.R3867* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV52333896, COSV52371775; called by muse, mutect2, varscan2
- FAT1 | c.9803C>A p.S3268* | Nonsense Mutation (SNP) | VAF 51/133 reads (38%) | catalogued as COSV71672462; called by muse, mutect2, varscan2
- FLNA | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV100774953; called by muse, varscan2
- NDST3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs775212321, COSV56628137, COSV56632105; called by muse, mutect2, varscan2
- NF2 | c.794C>A p.S265* | Nonsense Mutation (SNP) | VAF 45/93 reads (48%) | catalogued as COSV58528549; called by muse, mutect2, varscan2
- SACS | c.4724G>T p.R1575L | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as CM107270, COSV66538374, COSV66538520; called by muse, mutect2
- XIRP2 | c.3293G>A p.R1098K (on ENST00000628543; = p.R1273K on NM_152381.6) | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.321); catalogued as rs765920064, COSV99740593; called by muse, mutect2, varscan2
- ABCC4 | c.971T>C p.F324S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- AKAP12 | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ANKRD30B | c.2129C>A p.A710E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- BRD2 | c.2146A>G p.T716A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD46 | c.496C>G p.P166A | Missense Mutation (SNP) | VAF 87/123 reads (71%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNKSR2 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL17A1 | c.3017C>G p.S1006C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DDX3X | c.1960C>T p.Q654* (on ENST00000399959; = p.Q655* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- DENND2B | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- DOCK8 | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- E2F8 | c.1692G>C p.E564D | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- IBTK | c.647del p.T216Nfs*11 | Frame Shift Del (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- KANK1 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIF4A | c.2606A>G p.Y869C | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- MYEF2 | c.1688G>A p.G563D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); called by muse, mutect2
- NID2 | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR1S2 | c.699C>A p.C233* | Nonsense Mutation (SNP) | VAF 47/222 reads (21%) | called by muse, mutect2, varscan2
- PCDH15 | c.4537C>G p.Q1513E (on ENST00000644397 / NM_001354429.2; = p.D1473E on NM_001142770.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2
- PRR32 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RPS6KA3 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SUPT16H | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMEM145 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 115/200 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- TRIP12 | c.5304+2T>C p.X1768_splice | Splice Site (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- TRPC6 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- UBR5 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- WDFY4 | c.4982G>C p.R1661T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- AL592490.1 | c.2637G>A p.R879= | Silent (SNP) | VAF 28/364 reads (8%) | catalogued as COSV69426303, COSV69427629; called by muse, mutect2
- ARHGAP23 | c.2406G>T p.A802= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- BSN | c.5625G>A p.V1875= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- COL4A1 | c.2637A>G p.G879= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- FREM2 | c.474C>T p.D158= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- HSP90AA1 | c.1110C>T p.I370= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs1486720038; called by muse, mutect2, varscan2
- MAGEC3 | c.1245T>C p.P415= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV104403531; called by muse, mutect2, varscan2
- MYO1E | c.1446C>A p.L482= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV55691592, COSV55692252; called by muse, mutect2, varscan2
- SMG1 | c.10056T>C p.L3352= | Silent (SNP) | VAF 30/118 reads (25%) | called by muse, mutect2, varscan2
- TMC4 | c.807C>T p.I269= (on ENST00000617472 / NM_001145303.3; = p.I263= on NM_144686.4) | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- TMEM8B | c.87G>A p.T29= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs1221433813; called by muse, mutect2, varscan2
- UNC13B | c.3627G>A p.V1209= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs955125726; called by muse, mutect2, varscan2
- USP9X | c.2646C>T p.R882= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as rs755726740; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-230C>T | Intron (SNP) | VAF 20/175 reads (11%) | catalogued as COSV100025061, COSV100025510; called by muse, mutect2, varscan2
- MUC19 | n.9759G>C | RNA (SNP) | VAF 78/547 reads (14%) | called by muse, mutect2, varscan2
- SMARCA1 | c.*106G>A | 3'UTR (SNP) | VAF 69/177 reads (39%) | called by muse, mutect2, varscan2
